Somatic mutation profile of tumor specimen TCGA-AB-2828-03C (aliquot TCGA-AB-2828-03C-01W-0761-09) from TCGA case TCGA-AB-2828, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.8 years (20,393 days).
Specimen TCGA-AB-2828-03C: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c0a8bd3-ae90-403f-b501-cbf56dc646d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2828-11B (Solid Tissue Normal), aliquot TCGA-AB-2828-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/671d4688-19fc-4e3b-a30a-c042e1a594e0

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND2 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777621, CM144535, CM162083, COSV54223211, COSV54225487, COSV54226876; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAB29 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 186/1221 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.199); catalogued as rs1381553572; called by muse, mutect2, varscan2
- SPDYE1 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs62458722; called by muse, varscan2
- SYNE4 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1247417205, COSV53324081; called by mutect2, varscan2
- DTX4 | c.42C>A p.N14K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- ANK2 | c.9030T>C p.S3010= | Silent (SNP) | VAF 18/422 reads (4%) | called by muse, mutect2
- KRT2 | c.123C>T p.S41= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV59009025; called by mutect2, varscan2
